Somatic mutation profile of tumor specimen TCGA-W2-A7H5-01B (aliquot TCGA-W2-A7H5-01B-11D-A35I-08) from TCGA case TCGA-W2-A7H5, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 25.6 years (9,363 days).
Specimen TCGA-W2-A7H5-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88a68237-79e8-4e31-9fef-35ccec9f47f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W2-A7H5-10A (Blood Derived Normal), aliquot TCGA-W2-A7H5-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26052f88-7c57-4129-a445-c56666bcc89d

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH8 | c.6652G>A p.V2218I | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749048233, COSV59438407; called by mutect2, varscan2
- ALMS1 | c.1875A>G p.R625= | Silent (SNP) | VAF 13/128 reads (10%) | called by muse, mutect2
- OBSCN | c.13863G>A p.K4621= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1168405310; called by muse, mutect2, varscan2
